Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A69K, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A69K-01A (Primary Tumor).

[page 1 of 3]
PORT

CHF ICD-O.3
Carcinoma, papillary thyroid
path 8266/3
Carcinoma papillary & follicular
Site: Thyroid HAS 0739
5/16/13

Diagnosis:

A: Thyroid, total thyroidectomy

Tumor histologic type: papillary thyroid carcinoma, mixed classical and follicular variant of papillary thyroid carcinoma
Per TS, follicular variant < 99% - can be categorized as "classical".

Tumor size: two separate tumor foci measuring 3.1 cm and 2.2 cm in maximum dimension by gross examination

Tumor focality & laterality: multifocal, right lobe

Tumor capsule: partial encapsulated

Extent of invasion:

Capsular Invasion: not applicable

Lymphovascular invasion: not identified

Blood vascular invasion: not identified

Extra thyroidal extension: positive for minimal extrathyroidal extension

Surgical margins: carcinoma involves the resection margin of the right superior pole (see comment)

Status of thyroid gland away from tumor: multinodular thyroid

Lymph nodes: separately submitted

Size of largest metastasis (greatest dimension): not applicable

Extracapsular (perinodal) extension: not applicable

Other significant findings: incidental follicular adenoma 0.4 cm; benign parathyroid identified

AJCC Pathologic TNM Stage: pT3 pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph nodes, central neck dissection, compartment VII, excision

- No tumor seen in four lymph nodes (0/4).
- Benign thymic tissue identified.

[page 2 of 3]
Comment:

In the thyroidectomy specimen, the tumor nodule involving the superior pole appears to be partially encapsulated with some areas of capsular disruption. Tumor cells extend to the inked surfaces consistent with involvement of the surgical resection margin. Foci of tumor demonstrate areas of minimal extrathyroidal extension.

Clinical History:

-year-old female with thyroid carcinoma.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "thyroid".

Specimen fixation: Formalin

Type of specimen: Total thyroidectomy

Size and weight of specimen: Weight is 21 grams, left lobe (5.5 x 2.3 x 0.7 cm), right lobe (4.5 x 2.3 x 1.1 cm) connected by isthmus (1.7 x 1.3 x 1.0 cm), nodule attached to the right superior pole (3.1 x 1.8 x 1.2 cm).

Orientation: Suture at left superior pole. Inking: anterior capsule blue, posterior capsule black, isthmus yellow, and right superior pole nodule green.

Tumor location: Right lobe

Focality: Multifocal

Dominant tumor: Right

Tumor description: There are three nodules arbitrarily designated as A, B and C which are all located in the right lobe. Nodule A is loosely attached at the right superior pole (inked green) and is 3.1 x 1.8 x 1.2 cm. The external surface is pink/tan, smooth. The cut surface is solid pink/gray, smooth and rubbery. Nodule B is 0.4 cm from nodule A and is 2.2 x 2.1 x 1.0 cm. Nodule B is well-circumscribed smooth pink/tan and multi-nodular. Within the right inferior lobe is nodule C, 0.4 x 0.3 x 0.3 cm. This nodule is smooth, rubbery pink/tan and well-circumscribed. Tumor C is 0.7 cm from tumor B.

Tumor size: Nodule A (3.1 x 1.8 x 1.2 cm), Nodule B (2.2 x 2.1 x 1.0 cm), and Nodule C (0.4 x 0.3 x 0.3 cm)

[page 3 of 3]
Confinement/non-confinement: A, B and C nodules are all grossly confined, defer to light microscopy

Distance of tumor to capsular inked margin: Tumor A grossly abuts the green inked capsular margin; tumor B grossly abuts the anterior and posterior capsule and is 1.4 cm from the isthmus. Tumor A appears to be external to the thyroid gland, whereas tumor B is within the thyroid parenchyma. Tumor C grossly abuts the anterior capsule, 0.1 cm from the posterior capsule and is 1.5 cm from the isthmus margin.

Appearance of thyroid gland away from tumor: Red/brown and spongy. The left lobe is unremarkable.

Parathyroid: Not identified

Lymph nodes: No

Tissue for investigation: A portion of tumor A is given to tumor procurement foundation.

Digital photograph: No

Block Summary:

A1-A3 - Representative of tumor A
A4-A11 - Tumor B, submitted entirely
A12 - Right thyroid parenchyma between tumors B and C
A13-A14 - Tumor C
A15-A16 - Remainder of right lobe (right thyroid lobe submitted entirely)
A17-A19 - Representative of left lobe from superior towards inferior

Container B is additionally labeled "level 6 central lymph nodes" and consists of a 2.6 x 1.7 x 0.5 cm fragment of adipose tissue that contains five lymph node candidates, up to 0.3 cm in greatest dimension. By message received from Dr. , this specimen represents central neck dissection of compartment VII and this corrected information is reflected in the final diagnosis.

Block Summary:

B1 - Two lymph node candidates
B2 - Three lymph node candidates,

Criteria	lu	res	flu
Histo-A Discrepancy			✓
Reviewed: Initial	lu	res	flu

Source: NCI Genomic Data Commons file eee0aab5-72ec-4d2e-94b2-7b1db457b3ae (TCGA-DE-A69K.4AD8C17F-1301-4FF4-9B71-257AEFDE5484.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).